Surgical pathology report (de-identified scan), TCGA case TCGA-18-4086, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-4086-01A (Primary Tumor).

[page 1 of 6]
Surgical Pathology Consultation Report
* Amended *

SPECIMEN(S) RECEIVED

1. Soft-Tissue: Wedge Resection- Right Middle Lobe (Quick Section)
2. Lymph node: subcarinal ST7
3. Lymph node: interlobar ST11
4. Lymph node: lobar ST12
5. Lymph node: interlobar ST11
6. Lymph node: RT low paratracheal ST4R
7. Lymph node: INF pulm ligament ST9
8. LUNGS: right lower lobe

DIAGNOSIS

1. Lung, wedge resection (right middle lobe):
- a) Lung tissue with patchy interstitial chronic inflammation and fibrosis, usual interstitial pneumonia (UIP) pattern
- b) One lymph node with non-necrotizing granulomatous inflammation and focal mixed dust nodules (0/1)
- 2-7. Lymph nodes, resections (ST7 subcarinal, ST11 interlobar, ST12 lobar, ST11 interlobar, ST4R right lower paratracheal, ST9 inferior pulmonary ligament):
- Lymph nodes with non-necrotizing granulomatous inflammation, negative for malignancy (x6)
- Focal mixed dust nodules with central necrosis and hyalinization
8. Lung, resection (right lower lobectomy):
- a) Pleomorphic carcinoma [squamous cell carcinoma (90%) and spindle cell carcinoma (10%)], pT2N0, with:
- i) Maximum tumor dimension: 4.0 cm
- ii) Visceral pleural and vascular invasion not identified
- iii) Resection margins negative for tumor (closest margin: 18 mm, stapled parenchyma)
- iv) Five lymph nodes (4 lobar, 1 segmental) with non-necrotizing granulomas, negative for malignancy (0/5)

[page 2 of 6]
b) Lung tissue with patchy interstitial chronic inflammation and fibrosis, UIP pattern (see Comment)

SYNOPTIC DATA

Specimen Type:	Lobectomy
Laterality:	Right
Tumor Site:	RLl
Tumor Size:	Greatest dimension: 4.0 cm Additional dimensions: 3.0x3.0 cm
Histologic Type:	Carcinoma with pleomorphic, (variant): squamous cell carcinoma
Sarcomatoid, or sarcomatous elements (90%), spindle cell component (10%)	
Histologic Grade:	G3: Poorly differentiated
Pathologic Staging (pTNM):	pT2: Tumor with any of the following features of size or extent: greater than 3 cm in greatest dimension; involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung
metastasis	pN0: No regional lymph node
Margins:	pMX: Cannot be assessed
carcinoma	Margins uninvolved by invasive
closest margin: 18 mm	Distance of invasive carcinoma from
parenchymal margin	Specify margin: stapled
Direct Extension of Tumor:	None identified
Venous (Large Vessel) Invasion:	Absent
Arterial (Large Vessel) Invasion:	Absent
Small/Intermediate Blood Vessel Invasion:	Absent
Additional Pathologic Findings:	Other: interstitial fibrosis, UIP pattern; numerous non-necrotizing granulomas in lymph nodes
Neoadjuvant Treatment:	Unknown
Extension of Tumor:	Confined to lung

[page 3 of 6]
COMMENT

This case was initially signed out as a provisional report on [REDACTED], and has been amended to include results of immunohistochemical stains. The diagnoses have not changed from the original report.

The lymph nodes resected in the case (specimen 1-8) show diffuse involvement with well-formed non-necrotizing granulomatous inflammation. Occasional mixed dust nodules with central hyalinization and focal central necrosis are also present. Special stains for fungal elements and acid-fast organisms are negative. There is no evidence of metastatic carcinoma in any of the lymph nodes examined.

Sections of the tumor in specimen 8 show predominately moderately differentiated squamous cell carcinoma (90%), with a small component (10%) of a poorly differentiated spindle cell carcinoma that demonstrates shows multiple mitoses and severe cytologic atypia. There is no malignant cartilage, bone, or skeletal muscle identified in the spindle cell component. Immunohistochemistry shows the squamous cell component of the tumor to be positive for multiple cytokeratins (HMWK, CK5/6, AE1/AE3) and p63. The spindled component shows weak positive staining for CK5/6 and p63, with very focal positive staining for CK7. The EGFR shows strong membranous staining in approximately 90% of both the moderately differentiated component and the spindled component. Both components are negative for p53 and TTF-1. The findings are consistent with a pleomorphic carcinoma composed of predominantly squamous cell carcinoma (moderately differentiated, 90%) and pleomorphic spindle-cell carcinoma (poorly differentiated, 10%), pT2N0.

The residual lung parenchyma in both specimen 1 ("wedge resection right middle lobe") and specimen 8 ("right lower lobe") shows patchy interstitial fibrosis that appears accentuated in a subpleural distribution, with focal areas of architectural remodeling and cyst formation (microscopic honeycomb change). There is mild chronic interstitial inflammation associated with areas of fibrosis. Fibroblastic foci are readily identified. The blood vessels show focal fibrointimal thickening, likely secondary to the background inflammatory process, but no diagnostic evidence of active vasculitis. Granulomas are noted within an intraparenchymal lymph node (specimen 1), but are not identified in the lung parenchyma itself.

The overall findings in the lung tissue are in keeping with pulmonary

[page 4 of 6]
ROSS DESCRIPTION

1A frozen section

1B staple line margin

1C remaining back node/node

1D-1F lung

2. The specimen is labeled with the patient's name and as "subcarinal ST7".

Number of gray-tan tissue pieces: 10

Measurements: 0.5 x 0.5 x 0.4 cm to 2.7 x 1.7 x 1 cm.

The specimen is submitted in toto.

2A 1 node bisected

2B one node bisected

2C 5 nodes

2D one node bisected

2E one node quadrisected

2F one node trisected

3. The specimen is labeled with the patient's name and as "interlobar ST 11".

One piece of gray-tan tissue measuring 3 x 1.7 x 1.1 cm.

3A-3C trisected and submitted in toto

[page 5 of 6]
Number of gray-black tissue pieces: 4
Measurements: 0.5 x 0.3 x 0.2 cm to 2.2 x 1.5 x 1.2cm.
The specimen is submitted in toto.
4A 3 nodes
4B-4C one node trisected

5. The specimen is labeled with the patient's name and as "interlobar ST11".
One piece of gray-tan tissue measuring 1.3 x 0.6 x 0.6cm.
5A node bisected and submitted in toto

The specimen is labeled with the patient's name and as "right lower paratracheal ST4R".
One piece of tan black tissue measuring 1.4 x 1.2 x 0.6cm.
6A node bisected and submitted in toto

7. The specimen is labeled with the patient's name and as "inferior pulmonary ligaments ST9".
One piece of tan black tissue measuring 1.8 x 1.3 x 0.6 cm.
7A node bisected and submitted in toto

8. The specimen is labeled with the patient's name and as "right lower lobe".
Resection specimen: right lower lobe lung lobectomy measuring 10.5 x 10 x 6 cm.
Pleural surface: intact, smooth cobblestone/shows some surface adhesions, has an area of puckering measuring 1.7 x 1.2 cm.
Tumour:
Number of tumours: 1
Measurements: 4.0 x 3.0 x 3.0 cm.
Location: peripheral
Distance from resection margins: 2 cm from the bronchial resection margin; 1.8 cm from the closest stapled parenchymal resection margin.
Descriptive characteristics: White in colour, specks of black spots; solid consistency; poorly delineated
Lung parenchyma: Partly congested
Other lesions: No
Lymph Nodes: Multiple peribronchial lymph nodes are identified ranging from 0.3 to 1.7 x 0.9 x 0.8 cm in greatest dimension.
Frozen Section: No
Tissue Banking: Multiple pieces of tumor

[page 6 of 6]
[REDACTED]

Representative sections are submitted as follows:

8A bronchial resection margin

8B staple line margin

8C-8H tumor

8I lung parenchyma away from tumor

8J-8K 1 lobar node bisected in each cassette

8L 1 segmental node bisected

8M one lobar node bisected

8N one lobar node bisected

[REDACTED]

1A Lymph node with non-necrotizing granulomatous inflammation.
Slides received at 10.18 am; reported 10.20 am.

[REDACTED]

Source: NCI Genomic Data Commons file 1d5f51e7-fad9-4532-afc5-5e72f5b7ca98 (TCGA-18-4086.F83C1343-F2DC-4602-A34C-3A259EDFB343.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).